Somatic mutation profile of tumor specimen TCGA-06-0882-01A (aliquot TCGA-06-0882-01A-01W-0424-08) from TCGA case TCGA-06-0882, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 30.4 years (11,112 days).
Specimen TCGA-06-0882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a46052f7-a926-4c4a-ab3a-200a3a89d21c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0882-10A (Blood Derived Normal), aliquot TCGA-06-0882-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/443c35d7-e199-49d8-b2f7-2e0e4fc2eb9a

The open-access MAF lists 69 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 26, Frame Shift Ins 25, Silent 15, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 18/140 reads (13%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 168/1158 reads (15%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 80/286 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.11320dup p.A3774Gfs*37 | Frame Shift Ins (INS) | VAF 12/124 reads (10%) | catalogued as rs768698639; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- BEST3 | c.1332dup p.R445Qfs*58 | Frame Shift Ins (INS) | VAF 17/112 reads (15%) | catalogued as rs779566914; called by mutect2, varscan2
- CA8 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV100527353; called by muse, mutect2
- CEMIP2 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765559880, COSV65486383; called by muse, mutect2, varscan2
- CNTN6 | c.2696A>G p.K899R | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs143460057, COSV63189935; called by muse, mutect2, varscan2
- COL4A4 | c.2918C>T p.T973I | Missense Mutation (SNP) | VAF 46/703 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1466685743, COSV61630778; called by muse, mutect2
- CPS1 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104373018, COSV51805872; called by muse, mutect2, varscan2
- DDB1 | c.685dup p.A229Gfs*15 | Frame Shift Ins (INS) | VAF 33/256 reads (13%) | catalogued as rs757472327; called by mutect2, varscan2
- DENND2D | c.150dup p.Q51Afs*5 | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | catalogued as rs1433622303; called by mutect2, pindel, varscan2
- DRG2 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52754399; called by muse, mutect2, varscan2
- EP300 | c.4051G>T p.E1351* | Nonsense Mutation (SNP) | VAF 30/908 reads (3%) | catalogued as COSV54325882; called by muse, mutect2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 51/470 reads (11%) | catalogued as rs749953492; called by mutect2, varscan2
- FNTB | c.1047dup p.L350Afs*4 | Frame Shift Ins (INS) | VAF 32/276 reads (12%) | catalogued as rs768774237; called by mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 46/314 reads (15%) | catalogued as rs768450027; called by mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 28/192 reads (15%) | catalogued as rs752075537; called by mutect2, varscan2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 80/689 reads (12%) | catalogued as rs745545309; called by mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 30/120 reads (25%) | catalogued as rs780982673; called by mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 24/105 reads (23%) | catalogued as rs761558950; called by mutect2, varscan2
- ITGB7 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 171/602 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs755050035, COSV57238189; called by muse, mutect2, varscan2
- KDM1B | c.1991C>A p.A664D (on ENST00000449850; = p.A431D on NM_153042.4) | Missense Mutation (SNP) | VAF 152/771 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52809434; called by muse, mutect2, varscan2
- KDR | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 124/454 reads (27%) | catalogued as COSV55761453; called by muse, varscan2
- LEXM | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs201728919; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 42/245 reads (17%) | catalogued as rs757410385; called by mutect2, varscan2
- MKI67 | c.3817A>C p.I1273L | Missense Mutation (SNP) | VAF 54/1684 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1314643061, COSV64075361; called by muse, mutect2
- MSI1 | c.345dup p.L116Afs*15 | Frame Shift Ins (INS) | VAF 53/430 reads (12%) | catalogued as rs748469666; called by mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 30/208 reads (14%) | catalogued as rs761123152; called by mutect2, varscan2
- NHLH1 | c.321dup p.D108Rfs*8 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs760805876; called by pindel, varscan2
- OTOF | c.5027G>A p.R1676H (on ENST00000272371 / NM_194248.3; = p.R909H on NM_004802.4) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs143889717; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 78/627 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PLCB2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 171/706 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs761699247, COSV53031981; called by muse, mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 42/254 reads (17%) | catalogued as rs768056539; called by mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 46/296 reads (16%) | catalogued as rs778683789; called by mutect2, varscan2
- RAB3GAP2 | c.3184T>G p.L1062V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100741292, COSV62782993; called by muse, mutect2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 21/133 reads (16%) | catalogued as rs756557178; called by mutect2, varscan2
- REM1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199660041, COSV52427586; called by muse, mutect2, varscan2
- SETBP1 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs146321232, COSV99952004; called by muse, mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 74/458 reads (16%) | catalogued as rs746556543; called by mutect2, varscan2
- SYNE1 | c.631G>T p.V211F (on ENST00000367255 / NM_182961.4; = p.V218F on NM_033071.3) | Missense Mutation (SNP) | VAF 10/305 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as rs1010388763; called by muse, mutect2
- VPS52 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 216/750 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs750864533, COSV71403436; called by muse, mutect2, varscan2
- WNT16 | c.500dup p.C168Lfs*4 (on ENST00000222462 / NM_057168.2; = p.C158Lfs*4 on NM_016087.2) | Frame Shift Ins (INS) | VAF 54/429 reads (13%) | catalogued as rs771899177; called by mutect2, varscan2
- ZNF668 | c.1543dup p.Q515Pfs*41 | Frame Shift Ins (INS) | VAF 19/177 reads (11%) | catalogued as rs760397907; called by mutect2, varscan2
- CPNE4 | c.1073T>A p.F358Y | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2
- EGR1 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LPIN2 | c.2611G>T p.A871S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.804); called by muse, mutect2
- MYH13 | c.2585G>A p.R862K | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.99); called by muse, mutect2
- NSMCE2 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by mutect2, varscan2
- SNX18 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.883); called by mutect2, varscan2
- TARDBP | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 26/155 reads (17%) | called by mutect2, varscan2
- ULK2 | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CARMIL2 | c.1701C>T p.D567= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1251896133, COSV58024556; called by muse, mutect2
- DNAJA4 | c.963G>T p.L321= (on ENST00000343789; = p.L350= on NM_018602.3) | Silent (SNP) | VAF 26/522 reads (5%) | called by muse, mutect2
- DUXA | c.339A>G p.L113= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs747050180, COSV73729572; called by muse, mutect2, varscan2
- GRM8 | c.2637C>T p.G879= | Silent (SNP) | VAF 72/358 reads (20%) | catalogued as rs762951215, COSV58814787; called by muse, varscan2
- LAMA1 | c.6075G>A p.T2025= | Silent (SNP) | VAF 28/178 reads (16%) | catalogued as rs766719038, COSV67534312; called by muse, varscan2
- LHFPL6 | c.72C>T p.C24= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs774101101, COSV65444620; called by muse, mutect2, varscan2
- LYZL6 | c.405C>A p.G135= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1568418159; called by muse, mutect2, varscan2
- NAT9 | c.348G>A p.R116= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2583T>C p.T861= | Silent (SNP) | VAF 240/793 reads (30%) | catalogued as COSV62775557; called by muse, mutect2, varscan2
- POMT1 | c.1839G>A p.L613= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as rs762810201; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1584C>T p.S528= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV54759039; called by muse, mutect2, varscan2
- RPAP1 | c.4014A>G p.T1338= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs755165863, COSV55489876; called by muse, mutect2, varscan2
- STAB1 | c.2361C>T p.V787= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV58734001; called by muse, mutect2, varscan2
- TAS2R5 | c.636C>G p.V212= | Silent (SNP) | VAF 9/290 reads (3%) | called by muse, mutect2
- TMEM106B | c.420T>G p.R140= | Silent (SNP) | VAF 75/694 reads (11%) | catalogued as rs140753733; called by muse, mutect2
